Somatic mutation profile of tumor specimen 0DF5D0 from CCDI case PBBREX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,358 days).
Specimen 0DF5D0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f7d37e-a8d8-4f85-bf55-5c64c65ac3b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF5CX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f98d762b-d6f2-440a-89d8-363bc9883359

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'Flank 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MX2 | c.1914C>A p.S638R | Missense Mutation (SNP) | VAF 120/854 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- BRAF | c.1862-72C>T | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441264 G>T | 5'Flank (SNP) | VAF 24/924 reads (3%) | called by muse, mutect2
